MMRF case MMRF_2209 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/113abaaf-3eb2-4318-a5a1-d0564d7b942f

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 70 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 71.0 years (25,934 days); ISS stage: I; Days to last known disease status: 137 days; Days to last follow up: 137 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 8 days.
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 22 days; Days to treatment end: 125 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 173 days; Days to treatment end: 173 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 175 days; Days to treatment end: 175 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -13 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1430 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.49 mg/dL; Immunoglobulin G 6.08 g/L; Immunoglobulin A 0.45 g/L; Immunoglobulin M 0.15 g/L; Beta 2 Microglobulin 3.2 µg/mL; Lactate Dehydrogenase 3.05 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 4.27 ×10⁹/L; Platelets 313 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.13 mmol/L; Albumin 40 g/L; Total Protein 6.9 g/dL; Glucose 6.11 mmol/L; C-Reactive Protein 0.675 mg/dL.
- Day 85 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.88 mg/dL; Immunoglobulin G 16.6 g/L; Immunoglobulin A 3.28 g/L; Immunoglobulin M 0.36 g/L; Beta 2 Microglobulin 1.73 µg/mL; Lactate Dehydrogenase 1.83 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 12.7 ×10⁹/L; Absolute Neutrophil 9.5 ×10⁹/L; Platelets 506 ×10⁹/L; Creatinine 48.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.03 mmol/L; Albumin 27 g/L; Total Protein 7.2 g/dL; Glucose 7.37 mmol/L.
- Day 137: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.17 mg/dL; Immunoglobulin G 11.9 g/L; Immunoglobulin A 1.51 g/L; Immunoglobulin M 0.38 g/L; Beta 2 Microglobulin 1.83 µg/mL; Lactate Dehydrogenase 2.72 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.02 ×10⁹/L; Platelets 212 ×10⁹/L; Creatinine 48.6 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.13 mmol/L; Albumin 38 g/L; Total Protein 6.9 g/dL; Glucose 6.05 mmol/L.

Other clinical attributes
- Day -13: Weight: 76 kg; Height: 177 cm.

Biospecimens (2 samples)
- Sample MMRF_2209_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -13 days.
- Sample MMRF_2209_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -13 days.
